Surgical pathology report (de-identified scan), TCGA case TCGA-TQ-A7RM, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Sao Paulo, specimen TCGA-TQ-A7RM-01A (Primary Tumor).

Nature of material: Brain

Received on:

Macroscopy:

Received numerous irregular pieces of soft, blackish and brown tissue, measuring together 5.5 x 3.0 x 0.3 cm and weighing 4.0 g.

Microscopy:

Histological sections stained by the H & E show sections of glial neoplasm with hypercellular areas and moderately cellular areas with predominantly myxoid stroma with frequent microcystic degeneration. The cells are rounded with delicate cytoplasmic processes, often with clear perinuclear halos, showing moderately atypical, hyperchromatic and pleomorphic nuclei, with rare cells with gangliocytic phenotype. Are noted eventual gemistocytes. Presence of 7 mitoses per 10 HPF, sometimes atypical and numerous apoptosis figures. There are still pockets of microvascular proliferation. Were not detected foci of tumor necrosis.

Immunohistochemical study:

GFAP: (+)

NEU-C: (-)

Synaptophysin: (-)

VIMENTIN: (+)

KI-67: (+)

Diagnosis:

Product of biopsy in temporal lobe (side not specified):

- Anaplastic oligoastrocitoma, grade III (WHO).

ICD-O-3

Oligoastrocytoma, grade III 9382/3

Site: ^{CSCF} Brain, supratentorial NOS C71.0

^{Path} Brain, temporal lobe C71.2

gl 10/4/13

Source: NCI Genomic Data Commons file a734cc2e-3968-4005-8f29-936bcb74b0ea (TCGA-TQ-A7RM.C995C787-038D-46BD-A133-1775CBAECF27.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).